Somatic mutation profile of tumor specimen 0DAGP1 from CCDI case PBBKBC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.5 years (6,396 days).
Specimen 0DAGP1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea5477be-1577-4a7f-91c9-f4c9ab6d3940.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAGOU (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab7d9125-7278-4458-8b71-7ec18d7054f2

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, 3'UTR 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.1602+1G>A p.X534_splice | Splice Site (SNP) | VAF 26/235 reads (11%) | catalogued as rs1060502277, CS054921, COSV59497514; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C2orf16 | c.5468G>A p.R1823H | Missense Mutation (SNP) | VAF 106/541 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs753664844, COSV62674078; called by muse, mutect2, varscan2
- EPHA10 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427164882, COSV104397426; called by muse, mutect2
- GATA6 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.816); catalogued as rs1354600110; called by muse, mutect2
- KDM1A | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 48/525 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56502859; called by muse, mutect2
- MAP3K3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as rs766496256, COSV100675640; called by muse, mutect2, varscan2
- OR1A1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 59/735 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772402283, COSV58403180; called by muse, mutect2
- TEN1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 178/472 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs929018097, COSV67119353; called by muse, mutect2, varscan2
- TMEM132D | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV67161667; called by muse, mutect2, varscan2
- WDHD1 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs773989378; called by muse, mutect2, varscan2
- BEND5 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FANK1 | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 150/380 reads (39%) | called by muse, mutect2, varscan2
- GJC1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 143/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JCAD | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- LSS | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K4 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 225/695 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ORC4 | c.137dup p.H46Qfs*4 | Frame Shift Ins (INS) | VAF 25/222 reads (11%) | called by mutect2, varscan2
- ORC4 | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.051); called by mutect2, varscan2
- PCDH11Y | c.163G>A p.A55T (on ENST00000400457 / NM_032973.2; = p.A44T on NM_032971.3) | Missense Mutation (SNP) | VAF 238/351 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SCARA5 | c.1309del p.R437Afs*43 | Frame Shift Del (DEL) | VAF 122/341 reads (36%) | called by mutect2, varscan2
- STX11 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 119/379 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SYNE1 | c.17114G>A p.S5705N (on ENST00000367255 / NM_182961.4; = p.S5634N on NM_033071.3) | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNXB | c.5071C>T p.H1691Y (on ENST00000647633; = p.H1444Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/439 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UNC93B1 | c.906+5G>A | Splice Region (SNP) | VAF 114/274 reads (42%) | called by muse, varscan2
- ZNF747 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 223/575 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.747G>A p.T249= | Silent (SNP) | VAF 86/352 reads (24%) | catalogued as rs553802363, COSV59394352; called by muse, mutect2, varscan2
- FREM3 | c.5832A>G p.S1944= | Silent (SNP) | VAF 35/468 reads (7%) | called by muse, mutect2
- MGAT1 | c.1224G>A p.K408= | Silent (SNP) | VAF 67/182 reads (37%) | called by muse, mutect2, varscan2
- PRSS16 | c.25C>T p.L9= | Silent (SNP) | VAF 122/364 reads (34%) | called by muse, mutect2, varscan2
- TAS2R60 | c.129C>T p.G43= | Silent (SNP) | VAF 163/370 reads (44%) | catalogued as rs140806474, COSV100223663; called by muse, mutect2, varscan2
- TTC28 | c.5499A>G p.Q1833= | Silent (SNP) | VAF 119/331 reads (36%) | catalogued as rs984516842; called by muse, mutect2, varscan2
- DHX34 | c.*27C>T | 3'UTR (SNP) | VAF 37/102 reads (36%) | catalogued as rs370718716; called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- LYL1 | c.-11C>T | 5'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- TMEM61 | c.*7C>T | 3'UTR (SNP) | VAF 56/257 reads (22%) | called by muse, mutect2, varscan2
